Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABVN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABVN-TTR1-A (FFPE Recurrent).

[page 1 of 11]
Protocol ID 9671

+2457

Specimen #: [REDACTED] Received: [REDACTED]
Patient: [REDACTED] Proc. Date: [REDACTED] +2457
Ordering Dr: [REDACTED]

SPECIMEN SUBMITTED: Biopsy Abdominal Mass

PREOPERATIVE DIAGNOSIS: Malignant Mass

CLINICAL HISTORY: History of thyroid ca., breast ca.

GROSS DESCRIPTION:

Received from Radiology labeled "CT Guided Right Lower Quadrant Abdominal Mass" is a thread like piece of clear to grayish-white tissue measuring 3.2 cm. in length and up to 0.2 cm. in diameter. Specimen is marked with ink prior to processing for optimal recovery and sectioning. Bisected, each half submitted in an individual cassette. 2 cassettes.

FINAL DIAGNOSIS:

RIGHT SIDE ABDOMINAL MASS, CORE BIOPSY: MALIGNANT SPINDLE CELL TUMOR CONSISTENT WITH MALIGNANT GASTROINTESTINAL STROMAL TUMOR.

COMMENT: Immunohistochemical panel showed positive staining for Vimentin, CD117 and focal positivity for smooth muscle Actin and Desmin. IHC staining was negative for Pankeratin, S100 and CD34. This panel supports the diagnosis of GIST.

Dictated by: [REDACTED]

PATIENT: [REDACTED]
AGE/SEX: [REDACTED]
DOB: [REDACTED]

ACCT#: [REDACTED]
UNIT#: [REDACTED]
STATUS: DIS IN

LOC: [REDACTED]
ATTEND DR: [REDACTED]
DISCHARGE DATE: [REDACTED]

SURGICAL PATHOLOGY REPORT

+2457

[page 2 of 11]
MRN: [REDACTED]

DOB: [REDACTED]

Sex: F

Ordering MD: [REDACTED]

Attending MD: [REDACTED]

Admitting MD: [REDACTED]

Study Date Accession #Procedure CodeLocationProcedure

CT ABD PELV W/CONTRAST

+3514

Reason for Study

No reason given

*** Final Report ***

HISTORY:

Breast malignancy history of gastrointestinal stromal tumor.

COMMENTS:

Multiple axial computed tomographic images of the abdomen and pelvis were obtained following the intravenous injection of contrast material. Oral contrast had previously been administered. 5mm thick slices were obtained at 5 mm increments from the level of the dome of the right lobe of the liver to the ischial tuberosities.

The examination is seen in comparison to a prior CT portion of the PET CT examination dated [REDACTED] +3441. The liver is normal in size and appearance. The gallbladder is moderately distended with changes consistent with a phrygian cap. No intraluminal calcifications are seen. The wall of the gallbladder is of normal thickness. No dilated intra or extrahepatic biliary ducts are noted. The spleen is normal in size and appearance. The pancreas is well visualized and demonstrates no evidence of diffuse enlargement or focal mass. Dense calcification of the abdominal aorta and its branches is seen without evidence of aneurysm. There is no evidence of para-aortic mass or adenopathy. The kidneys are normal in size and function. No cortical cystic or enhancing masses are seen. There is no evidence of hydronephrosis. No calcifications are seen within the kidneys. The adrenal glands are well-visualized and are unremarkable. Degenerative changes are noted in the lumbar spine. The previously described calcified mass in the right pelvis is unchanged in appearance measuring approximately 4.7 x 2.6 cm in cross-section. The appendix is not identified as a discrete structure. No pericecal inflammatory changes are seen. Scattered diverticula are seen involving the sigmoid colon without evidence of pericolic inflammatory process. There is moderate thickening of the wall of the stomach predominately involving the fundus and body. The stomach is not distended. No perigastric inflammatory changes are seen. The urinary bladder is normal in size and appearance. The uterus is not seen compatible with the patient's history of previous hysterectomy. Calcified phleboliths are seen in the pelvis. There is no evidence of free abdominal fluid or free intraperitoneal air.

IMPRESSION:

Distended gallbladder without evidence of intraluminal calcification or pericholecystic inflammatory process.

Thickening of the wall of the fundus and body of the stomach without discrete mass or perigastric inflammatory change.

Stable calcified mass in the right pelvis.

Dictated on: [REDACTED]

+3514

Interpreted by: [REDACTED]

Transcribed by: [REDACTED]

Printed [REDACTED]

[page 3 of 11]
[REDACTED]

[REDACTED]

[REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Sex: F

Ordering MD:

[REDACTED]

Attending MD:

[REDACTED]

Admitting MD:

[REDACTED]

Signed by:

+3514

[REDACTED]

[page 4 of 11]
Radiology

Protocol ID 9671

MRN:

DOB:

Sex: F

Ordering MD:

Attending MD:

Admitting MD:

Study Date

Accession #

Procedure Code

Location

Procedure

+3243

PETCT,SK MID THIGH,DIAGNS
SUBQ

Reason for Study

No reason given

***** Final Report *****

HISTORY:

female with a history of GIST tumor. Currently on chemotherapy. No history of radiotherapy examination is ordered for restaging. Initial blood glucose of 85 mg/dL.

COMMENTS:

PET/CT imaging was performed from the level of the mid brain to the level of the mid thigh following the intravenous administration of 16.67 mCi of FDG 18. Concurrent CT images were obtained for localization and attenuation correction purposes only. Comparison is made with CT chest, abdomen, and pelvis from +3159

Physiologic FDG uptake within the visualized head and neck.

Physiologic FDG uptake also within the chest. Left lung base scarring or atelectasis. No masses or consolidation. No mediastinal, hilar, or axillary lymphadenopathy. No pleural or pericardial effusion. Status post left mastectomy. Atherosclerotic calcification of the aorta and its branches, including the coronary arteries.

Physiologic FDG uptake within the abdomen and pelvis. Right pelvic soft tissue mass measuring 4.4 x 2.8 cm, previously 4.7 x 2.9 cm. Interval increase in the amount of internal calcification. The mass does not hypermetabolic. Normal adrenal glands. Cholelithiasis. Diverticulosis coli without diverticulitis.

Skin ulceration medial left upper thigh with adjacent skin thickening. Small fat-containing left ventral hernia, unchanged.

Physiologic FDG uptake within the bone marrow. No lytic or blastic bone lesions. Degenerative changes within the spine. Dental amalgam.

IMPRESSION:

No hypermetabolic disease. Right pelvic soft tissue mass is stable to slightly decreased in size compared to the prior study. There is interval increase in the amount of internal calcification. No new masses.

Small medial left upper thigh skin ulceration.

See comment.

Dictated on:

Interpreted by:

+3247

Printed

[page 5 of 11]
Radiology

Protocol ID 9671

MRN: [REDACTED]

DOB: [REDACTED]

Sex: F

Ordering MD: [REDACTED]

Attending MD: [REDACTED]

Admitting MD: [REDACTED]

Transcribed by: [REDACTED]

Signed by: [REDACTED]

+3247

Printed [REDACTED]

[page 6 of 11]
Protocol ID 9671

Patient Name: [REDACTED]
MRN: [REDACTED]
Date of Birth: [REDACTED]
Patient Gender: Female

Visit Number: [REDACTED]
Visit Type: [REDACTED]
Patient Location: [REDACTED]

Other

RESULT STATUS:
DOCUMENT SUBJECT:

Final
[REDACTED] PET/CT TUMOR IMAGING SKULL BASE TO THIGHS

ELECTRONICALLY SIGNED BY:
SERVICE DATE/TIME:

+2472

[REDACTED] PET/CT TUMOR IMAGING SKULL BASE TO THIGHS

PATIENT NAME: [REDACTED]
PATIENT MRN: [REDACTED]
PATIENT DOB: [REDACTED]
EXAM DATE OF SERVICE: [REDACTED] +2472
EXAM NUMBER: [REDACTED]
ORDERING PHYSICIAN: [REDACTED]

EXAMINATION:
PET/CT TUMOR IMAGING SKULL BASE TO THIGHS

CLINICAL HISTORY:

Recurrent GIST. Per outside radiology reports the patient has a history of breast cancer status post left mastectomy, requiring cancer status post partial thyroidectomy, and GIST status post small bowel resection in

[REDACTED] Year of +412

COMPARISON:

Prior outside abdominal CT's, most recent from [REDACTED] +2457 and PET/CT from [REDACTED] +1117

TECHNIQUE:

PET images were obtained from the base of the skull to the proximal thighs 90 minutes after FDG injection. Images were reconstructed in the axial and coronal planes. Axial, coronal and sagittal images were reconstructed from helically acquired CT data obtained through the same regions without IV contrast. Comment: requested intravenous contrast was not administered due to history of contrast allergy and lack of premedication. Oral contrast was given.

Date/Time Printed: [REDACTED]
Printed By: [REDACTED]

[page 7 of 11]
MRN [REDACTED]

Other

RADIOPHARMACEUTICAL:
F-18 FDG 9.14 mCi IV

FINDINGS:

Neck: There is no FDG avid neck mass or adenopathy. There is physiologic uptake within Waldeyer's ring. The visualized paranasal sinuses and mastoid air cells are clear. The skull base is unremarkable. The naso-, oro- and hypopharynx are unremarkable. The parotid glands and submandibular glands are unremarkable. There are postoperative changes of right hemithyroidectomy.

Chest: There are mildly FDG avid subcentimeter mediastinal and hilar nodes, the largest measuring +1117 approximately 8 mm in short axis. These nodes are unchanged from the PET-CT dated [REDACTED] and are likely reactive. There is no supraclavicular, internal mammary, or axillary lymphadenopathy. No pleural effusion. Small amount of atelectasis in the dependent lung bases. Heart size is normal. There is atherosclerotic calcification of the aorta and coronary arteries. No pericardial effusion. There is mild increased radiotracer FDG avidity involving the thoracic esophageal mucosa.

Abdomen: There is a large 7.1 x 5.9 x 6.1 cm mass in the right lower quadrant that demonstrates heterogeneous peripheral hypermetabolic regions and more central photopenic regions, consistent with central necrosis. This mass demonstrated heterogeneous peripheral enhancement on the prior contrast-enhanced CT. A lobulated component extends from the inferior aspect of the main mass and insinuates between several loops of small bowel. There is an intensely FDG avid 2.1 x 3.2 cm lobulated soft tissue mass within the mesentery just superior to the dome of the bladder and additional 1.8 x 1.3 cm intensely FDG avid mass just inferior to the hepatic flexure in the right upper quadrant (axial image 138/275). There are innumerable additional mesenteric and peritoneal nodular soft tissue implants, predominantly localized to the central lower abdomen and right lower quadrant demonstrating varying degrees of moderate to intense FDG activity. Additional moderate to intensely FDG avid nodular soft tissue implants are noted within the cul-de-sac, the largest measuring 2.0 x 1.7 cm (axial image 197/275).

There is moderate increased mucosa FDG within the underdistended stomach, nonspecific. The liver, spleen, pancreas, bilateral adrenal glands and gallbladder are unremarkable. There is no free air or free fluid. The kidneys are normal in appearance without evidence of mass or hydronephrosis. The abdominal aorta is normal in course and caliber with diffuse atherosclerotic calcification. There is a non FDG avid 1.1 x 1.3 cm calcified nodule anterior to the IVC (axial image 131/275) that is stable dating back to the CT from [REDACTED] non-specific year of 1117 but possibly a calcified node. The bowel is nonobstructed. There is sigmoid diverticulosis. Small fat containing periumbilical hernia with a tiny fascial defect.

Pelvis: The bladder is unremarkable for level of distention. There are postoperative changes of hysterectomy.

Date/Time Printed: [REDACTED]
Printed By: [REDACTED]

[page 8 of 11]
MRN [REDACTED]

Other

No adnexal mass lesion. Interval resolution of the previously seen free fluid in the cul-de-sac. There is no FDG avid pelvic or inguinal lymphadenopathy.

Musculoskeletal: There are no osseous FDG avid lesions identified. There are no blastic or lytic skeletal lesions. There are sclerotic changes of the sacroiliac joints and pubic symphysis. Multilevel degenerative changes of the spine, most significant in the cervical spine. There is mild non FDG avid superior endplate compression deformity at L3 and 6 mm degenerative anterolisthesis of L4 on L5. Postoperative changes of left mastectomy. Mild joint centered uptake in the shoulders.

IMPRESSION:

1. Large hypermetabolic centrally necrotic mass in the right lower quadrant with innumerable moderate to intensely FDG avid mesenteric and peritoneal soft tissue implants, consistent with extensive metastatic disease.
2. Postoperative changes of left mastectomy and right hemithyroidectomy.
3. Moderate increased mucosal FDG uptake within the underdistended stomach and mild increased FDG avidity within esophagus. This is most likely inflammatory gastritis and esophagitis from reflux. Please correlate clinically.

Results discussed with [REDACTED]

+2472

[REDACTED] is the dictating resident.

Attending radiologist signature indicates review of both the images and the report and that the attending radiologist agrees with the interpretation. Preliminary reports may not have been reviewed as yet by the attending radiologist.

Dictated: [REDACTED]

Reviewed and signed: [REDACTED]

Date drafted: [REDACTED]

Date of final signature: [REDACTED]

+2472

[page 9 of 11]
Patient: [REDACTED]
PROCEDURE: CT ABD PELV COMBINED*
Location: CAT SCAN
Date: [REDACTED] +2457
Order #: [REDACTED]
ATT Physician: [REDACTED]
ORD Physician: [REDACTED]

ACT: [REDACTED] U# [REDACTED]
Sex: F Age/Dob: [REDACTED]
HM PH: [REDACTED]
Room #: [REDACTED]

RADIOLOGY RESULTS

HISTORY:

Abdominal pain

IMPRESSION:

Again demonstrated is a heterogeneous 7.0 x 6.0 cm mass in the right lower quadrant below the tip of the cecum. Numerous enlarged mesenteric lymph nodes are demonstrated consistent with lymphadenopathy. Neoplastic mass right lower quadrant should be considered. Suggest biopsy of the right lower quadrant mass.

Small amount of free fluid within the pelvis.

See comment.

COMMENT:

Axial images of the abdomen and pelvis were obtained before and after intravenous contrast administration. Oral contrast also administered. This study was performed [REDACTED] at [REDACTED] and correlated with prior examinations most recently dated [REDACTED] +2455.

The patient is status post left mastectomy. Fibrotic stranding again demonstrated in the left lung base.

There is no evidence of pneumoperitoneum or abdominal aortic aneurysm. There are vascular atherosclerotic calcifications and there are degenerative changes involving the spine.

The liver, spleen, adrenal glands, kidneys and pancreas are stable in appearance.

Again demonstrated is a heterogeneous 7.0 x 6.0 cm mass in the right lower quadrant below the tip of the cecum. Numerous enlarged mesenteric lymph nodes are demonstrated consistent with

[page 10 of 11]
Patient: [REDACTED]

Department of Radiology
CONT'D

lymphadenopathy. Neoplastic mass right lower quadrant should be considered. Suggest biopsy of the right lower quadrant mass.

Unchanged small soft tissue containing left periumbilical ventral hernia demonstrated.

There is no evidence of intestinal obstruction. There is a trace amount of free fluid within the pelvis. Sigmoid diverticulosis again demonstrated without acute diverticulitis.

Electronically Signed & Dictated By:
[REDACTED]

Report #: [REDACTED]

Dictated: [REDACTED]

Transcribed By: [REDACTED]

Date Results Sent: [REDACTED] +2457
Copy

CC:

PCP: [REDACTED]
[REDACTED]

[page 11 of 11]
ER-ABVN-TTR1-PR Redacted

Patient:
Pt #:
DOB/Age/Sex:
Patient Phone:
Patient Address:

Submitting MD:
Additional MD's:

Accession #:
Patient Type:
Location:
Admit Date:

Collected:
Received:

PATHOLOGY CONSULT REPORT

MATERIALS RECEIVED

Received are 11 slides, 1 paraffin block, and an accompanying pathology report labeled from
for on the above named person.

The original procedure date for case was:

All slides and a consultation report to be returned to:

ICD-0-3
Malignant gastrointestinal stromal
tumor 8936/3

CLINICAL HISTORY

Slide Consultation

Primary Site: small intestine, nos C17.9
Recurrence Site: abdomen, nos C76.2

MICROSCOPIC EXAMINATION

Performed.

ICD-10
Recurrence Site: Abdomen C76.2

FINAL DIAGNOSIS

ABDOMINAL MASS, BIOPSY (OUTSIDE SLIDE REVIEW, ONE GLASS SLIDE,
-- MALIGNANT SPINDLE CELL TUMOR CONSISTENT WITH MALIGNANT GASTROINTESTINAL STROMAL TUMOR
(GIST)
-- SEE COMMENT

COMMENT: This opinion is based on review of one submitted slide. Per the outside report, the tumor cells show positive staining with vimentin, CD117 and focal positivity for smooth muscle actin and desmin while negative with pankeratin, S100 and CD34. There is approximately 1% tumor necrosis. 98% of the nuclei in the needle core biopsy are tumor nuclei.

This assessment is in agreement with the original pathology report. The slide was also reviewed with with agreement.

Electronically Signed

This report may include one or more special stain or immunohistochemical stain results that use analyte specific reagents. All stains have been performed and interpreted at the specified. All positive and negative controls have been reviewed by the pathologist and are satisfactory unless otherwise specified. The tests were developed and their performance characteristics determined by the

Source: NCI Genomic Data Commons file 86710156-fb19-486d-899f-6b36a81315d9 (ER0096 ER-ABVN Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).